Surgical pathology report (de-identified scan), TCGA case TCGA-50-6591, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-6591-01A (Primary Tumor).

PATIENT HISTORY:

Lung mass.

PRE-OP DIAGNOSIS: Lung mass.

POST-OP DIAGNOSIS: Lung mass.

PROCEDURE: Not given.

ADDENDA:**Addendum**

The Department of Pathology is in receipt of

Addendum

Sections of part 5 "rib", shows normal bone and bone marrow with trilineage representation and maturation. No evidence of malignancy.

FINAL DIAGNOSIS:**Summary Statement**

The left lower lobe superior segmentectomy shows a poorly differentiated adenocarcinoma with clear cell change and amyloid like stroma associated with visceral pleural and angiolymphatic invasion without involvement of N1 or N2 lymph nodes. Diameter 8.0 cm. Pathologic stage T2N0MX.

PART 1

AND 2: LUNG, "CARINA", AND "RIGHT ENDOBRONCHIAL BIOPSY", BRONCHOSCOPIC BIOPSY --

FRAGMENTS OF RESPIRATORY MUCOSA WITH NO SIGNIFICANT ABNORMALITY.

PART 3: LYMPH NODE, LOWER LOBE 11, BIOPSY --

FOUR FRAGMENTS OF LYMPH NODES WITH NO EVIDENCE OF METASTATIC CARCINOMA.

PART 4: LYMPH NODE, SUPERIOR SEGMENT LEVEL 11, BIOPSY --

SOLITARY FRAGMENT OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

PART 5: RIB, SITE UNSPECIFIED, RESECTION --

SPECIMEN UNDERGOING DECALCIFICATION. ADDENDUM REPORT TO FOLLOW.

PART 6: LUNG, SUPERIOR SEGMENT LEFT LOWER LOBE, WEDGE RESECTION --

- A. POORLY DIFFERENTIATED ADENOCARCINOMA WITH CLEAR CELL CHANGE AND AMYLOID LIKE STROMA ASSOCIATED WITH VISCERAL PLEURAL AND ANGIOLYMPHATIC INVASION. DIAMETER 8.0 CM. ALL MARGINS FREE. MINIMAL HOST LYMPHOCYTIC RESPONSE. PATHOLOGIC STAGE T2N0MX.
- B. MILD EMPHYSEMATOUS CHANGE.

PART 7: LYMPH NODE, LEVEL 7 LYMPH NODE, BIOPSY --

SOLITARY LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

PART 8: LYMPH NODE, LEVEL 5 LYMPH NODE, BIOPSY --

FOUR FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

PART 9: LYMPH NODE, LEVEL 6 LYMPH NODE, BIOPSY --

FOUR FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

PART 10: LYMPH NODE, LEVEL 9 LYMPH NODE, BIOPSY --

SOLITARY FRAGMENT OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY LUNG TUMORS**

TUMOR LOCATION: Left Lower Lobe
LUNG SEGMENT(S) INVOLVED: Superior
PROCEDURE: Segmental
TUMOR SIZE: Maximum dimension: 8.0 cm
Minor dimension: 6.5 cm
GROSS SATELLITES: Number of gross satellite lesions: 0
TUMOR TYPE: Invasive adenocarcinoma
HISTOLOGIC GRADE: G3, Poorly differentiated
MICROSCOPIC SATELLITES: Number of microscopic satellite lesions: 0

EXTRAPULMONARY PARENCHYMAL

EXTENSION/INVASION OF TUMOR: Visceral pleura
ANGIOLYMPHATIC INVASION: Yes
TUMOR NECROSIS: < or = to 50%
SURGICAL MARGIN INVOLVEMENT: No
SURGICAL MARGIN SITE: Distance of invasive tumor to closest margin: 5 mm, Parenchymal margin
INFLAMMATORY(DESMOPLASTIC) REACTION: Mild

N1 LYMPH NODES: Number of N1 lymph nodes positive: 0
Number of N1 lymph nodes examined: 5
N2 LYMPH NODES: Number of N2 lymph nodes positive: 0
Number of N2 lymph nodes examined: 10

UNDERLYING DISEASE(S): Emphysema

T STAGE, PATHOLOGIC: pT2

N STAGE, PATHOLOGIC: pN0

M STAGE, PATHOLOGIC: pMX

ANCILLARY STUDIES: Histochemical stains, FISH studies, Molecular studies

Comment: PAS stains show abundant cytoplasmic glycogen and PAS-D and mucicarmine stains are positive for mucin. Elastic tissue stain show pleural invasion. Congo Red stains are negative.

Source: NCI Genomic Data Commons file 682dcbd0-523b-40fe-aa6e-160c187cd703 (TCGA-50-6591.D1BB9FEB-2CD4-40FD-A4D6-300D16B29D51.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).